Surgical pathology report (de-identified scan), TCGA case TCGA-G6-A8L7, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G6-A8L7-01A (Primary Tumor).

[page 1 of 2]
ICD-3
Carcinoma, clear cell 8310/3
Site: R Kidney NOS C64.9
JAS 11/24/13

SPECIMENS:

A. RIGHT KIDNEY AND TUMOR

SPECIMEN(S):

A. RIGHT KIDNEY AND TUMOR

DIAGNOSIS:

- A. RIGHT KIDNEY AND TUMOR (NEPHRECTOMY SPECIMEN):
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, FUHRMAN GRADE III, WITH EXTENSIVE AREAS OF NECROSIS OF LOWER POLE OF RIGHT KIDNEY.
- SIZE OF TUMOR – 5.3 X 4.9 X 2.5 CM
- URETERAL AND VASCULAR HILAR MARGINS – NEGATIVE FOR TUMOR.
- TWO LYMPH NODES – NEGATIVE FOR TUMOR (0/2).
- SEE NOTE.

Note: Tumor shows extensive areas of necrosis wherein calcifications are seen there is no identifiable penetration of capsule or extension into the perirenal fat.

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: RIGHT KIDNEY AND TUMOR

Specimen Type: Radical nephrectomy

Without adrenal gland

Laterality: Right

Tumor Site: Lower pole

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 5.3cm

Additional dimensions: 4.9cm x 2.5cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Clear cell renal cell carcinoma 8310/3

Histologic Grade (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 u; nucleoli large and prominent

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Not present

Regional Lymph Nodes: Negative 0 / 2

Additional Findings: Tumor necrosis

Pathological Staging (pTNM): pT 1b N 0 M X

GROSS DESCRIPTION:

A. RIGHT KIDNEY AND TUMOR, NEPHRECTOMY:

Received in fresh state is a specimen labeled with patient's name and identification number and labeled as "right kidney and tumor" The specimen consists of 289 grams resected right kidney and perirenal fat with total dimensions of 14.5 x 7.0 x 4.2 cm. The attached ureter measures 7 cm in length with external diameter of 0.3 cm. The kidney proper measures 12.5 x 4.5 x 2.5 cm., which on cut sections shows a seemingly circumscribed tumor with central necrosis involving the lower pole and measures 5.3 x 4.9 and 2.5 cm. Grossly, the tumor is seen closed to capsule without gross extension to perirenal fat. The renal pelvis and mucosa of ureter appears to be grossly not remarkable. There is no gross extension of tumor to the renal pelvis. The remainder of the kidney parenchyma of the upper pole shows the usual appearance with no other identifiable tumor focus. Two lymph nodes identified measuring 0.7 and

[page 2 of 2]
grossly free of tumor . The is no identifiable adrenal gland. Multiple sections submitted in cassettes labeled as follows:

A1: ureter and hilar blood vessels

A2: section from ureter

A3-A7: sections of tumor with included capsule

A8: section of tumor with adjacent kidney parenchyma.

A9: normal-appearing parenchyma

A10: lymph nodes

CLINICAL HISTORY:

Right renal mass

PRE-OPERATIVE DIAGNOSIS:

None given

Gross Dictation:., Pathologist,

Microscopic/Diagnostic Dictation: Pathologist.

Final Review:., Pathologist.

Final:., Pathologist,

Source: NCI Genomic Data Commons file b4be20a9-f854-4f95-aa93-54cd6256dc45 (TCGA-G6-A8L7.6C510354-EC94-4D72-B9A6-9FC6CBAFA8AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).